Somatic mutation profile of tumor specimen C3L-01275-01 (aliquot CPT0073730009) from CPTAC case C3L-01275, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.1 years (23,768 days).
Specimen C3L-01275-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bc06f66-600b-42ba-8487-a1498decdf48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01275-72 (Blood Derived Normal), aliquot CPT0073760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/089be604-7898-424d-a857-a5a709588465

The open-access MAF lists 1,355 somatic variants for this specimen: 924 protein-altering or splice-affecting, 255 silent, 176 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 589, Silent 255, Frame Shift Del 223, Intron 95, Frame Shift Ins 43, Nonsense Mutation 24, 5'UTR 23, 3'UTR 23, RNA 23, Splice Region 18, Splice Site 17, In Frame Del 8.

Variants (750 of 1,355; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.9253dup p.T3085Nfs*26 | Frame Shift Ins (INS) | VAF 32/193 reads (17%) | catalogued as rs80359752; ClinVar: pathogenic; called by mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 32/147 reads (22%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 88/361 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 132/360 reads (37%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 34/218 reads (16%) | catalogued as rs1064796057, CM163843, COSV51625840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 42/174 reads (24%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYO15A | c.1185dup p.E396Rfs*36 | Frame Shift Ins (INS) | VAF 94/518 reads (18%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 49/243 reads (20%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 140/350 reads (40%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.2076del p.P693Qfs*3 | Frame Shift Del (DEL) | VAF 52/361 reads (14%) | catalogued as rs768943469; called by mutect2, pindel, varscan2
- ACACB | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs753882249, COSV58128382; called by muse, mutect2, varscan2
- ADGRA3 | c.3548G>A p.R1183Q | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1360396330, COSV99293873; called by muse, mutect2, varscan2
- ADPRHL1 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1008433495; called by muse, mutect2, varscan2
- ADRB1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs238741; called by muse, mutect2, varscan2
- AIFM2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as rs139590841; called by muse, mutect2
- AL031777.2 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1249330554, COSV61912126; called by muse, mutect2, varscan2
- AMDHD2 | c.1084G>A p.A362T (on ENST00000293971 / NM_001330449.2; = p.A392T on NM_015944.4) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs769069314, COSV53550440; called by muse, mutect2, varscan2
- ANKFN1 | c.3262G>A p.D1088N (on ENST00000653862; = p.D941N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/401 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); catalogued as rs145174606, COSV73718568; called by muse, mutect2, varscan2
- ANO6 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as rs1272161801, COSV57657063; called by muse, mutect2, varscan2
- AP3B2 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1406634414; called by muse, mutect2, varscan2
- APAF1 | c.2510C>T p.T837M (on ENST00000551964 / NM_181861.2; = p.T826M on NM_013229.3) | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as rs200461221, COSV59667778; called by muse, varscan2
- APC | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as CM080053, COSV57376691; called by muse, mutect2, varscan2
- APEH | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs372455516; called by muse, varscan2
- APOA5 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 114/638 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs750842108, CD105008, COSV57063244; called by muse, mutect2, varscan2
- APOB | c.7295A>G p.Y2432C | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51931152; called by muse, mutect2, varscan2
- AQP12B | c.337G>A p.A113T (on ENST00000621682; = p.A125T on NM_001102467.2) | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1374452728, COSV68183864; called by muse, mutect2, varscan2
- AQP9 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs527316680; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 50/227 reads (22%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 30/112 reads (27%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARID1A | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 71/356 reads (20%) | catalogued as COSV61372089, COSV61376935; called by muse, mutect2, varscan2
- ASGR1 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52649546; called by muse, mutect2, varscan2
- ATG12 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs774173329; called by muse, mutect2, varscan2
- ATP2B3 | c.2573C>T p.T858M | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54844911; called by muse, varscan2
- BAG6 | c.1169del p.P390Qfs*61 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | catalogued as rs745882580; called by mutect2, varscan2
- BAMBI | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); catalogued as COSV100977500; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 42/189 reads (22%) | catalogued as rs747119215; called by mutect2, varscan2
- BCAS4 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs770581966; called by muse, mutect2, varscan2
- BMP2K | c.3304C>T p.R1102W | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs757576380; called by muse, mutect2, varscan2
- BRCA2 | c.6101G>A p.R2034H | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80358849, CM074720, COSV66452039; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / not provided; called by muse, mutect2, varscan2
- C1orf116 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs569420144, COSV100847966; called by muse, mutect2, varscan2
- C3 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 26/477 reads (5%) | catalogued as COSV55573038; called by muse, mutect2
- C8orf74 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs745881705, COSV100262594; called by muse, mutect2, varscan2
- CABLES1 | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV56938773, COSV99908544; called by muse, mutect2, varscan2
- CACNA1I | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.033); catalogued as rs758158318; called by muse, mutect2, varscan2
- CACNA1I | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs368239983, COSV60813047; called by muse, mutect2, varscan2
- CACNA1S | c.3686G>A p.R1229H | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774416016, COSV62939289; called by muse, mutect2, varscan2
- CALY | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs930656342; called by muse, mutect2, varscan2
- CAPN1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 64/371 reads (17%) | catalogued as rs751243573, COSV54201789; called by muse, mutect2, varscan2
- CARD10 | c.2177T>C p.V726A | Missense Mutation (SNP) | VAF 87/523 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs765583656; called by muse, mutect2, varscan2
- CASKIN1 | c.3406_3408del p.E1136del | In Frame Del (DEL) | VAF 61/268 reads (23%) | catalogued as rs1237491394; called by mutect2, pindel, varscan2
- CASP4 | c.128del p.K43Rfs*37 | Frame Shift Del (DEL) | VAF 37/300 reads (12%) | catalogued as rs772291949; called by mutect2, varscan2
- CASP8 | c.815C>T p.T272M (on ENST00000432109 / NM_033355.3; = p.T289M on NM_001228.4) | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139337151; called by muse, mutect2, varscan2
- CBY2 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs759482874, COSV60119002; called by muse, mutect2, varscan2
- CCDC116 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.481); catalogued as rs757373745, COSV99489171; called by muse, mutect2, varscan2
- CCDC166 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.144); catalogued as COSV72638857; called by muse, mutect2, varscan2
- CCDC171 | c.2075del p.N692Tfs*5 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs1463058740; called by mutect2, pindel, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC3 | c.215del p.G72Afs*150 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | catalogued as COSV66560484; called by mutect2, pindel, varscan2
- CCDC74A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs781391784, COSV54606562; called by muse, mutect2
- CCDC77 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs374200726; called by muse, mutect2, varscan2
- CCNE2 | c.-26-6dup | Splice Region (INS) | VAF 25/124 reads (20%) | catalogued as rs749097567; called by mutect2, pindel, varscan2
- CD7 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746691752; called by muse, mutect2, varscan2
- CDH24 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1049872445, COSV99400540; called by muse, mutect2
- CDH7 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs116566190, COSV59882861, COSV59896451; called by muse, mutect2, varscan2
- CDHR4 | c.1912dup p.H638Pfs*100 | Frame Shift Ins (INS) | VAF 30/160 reads (19%) | catalogued as rs932849375; called by mutect2, pindel, varscan2
- CDK18 | c.913G>A p.E305K (on ENST00000506784 / NM_212503.3; = p.E275K on NM_002596.4) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV63729083; called by muse, mutect2, varscan2
- CEBPE | c.836del p.G279Vfs*19 | Frame Shift Del (DEL) | VAF 45/304 reads (15%) | catalogued as rs1363394381, COSV52829926; called by mutect2, pindel, varscan2
- CELA2B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs535515233, COSV62747409; called by muse, mutect2, varscan2
- CELSR3 | c.70_72del p.L24del | In Frame Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1304592734; called by pindel, varscan2
- CENPI | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs761693180, COSV54500533; called by muse, mutect2, varscan2
- CEP164 | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.787); catalogued as rs1454720853, COSV54045610; called by muse, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP47 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs750135715; called by muse, mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 31/155 reads (20%) | catalogued as rs762321510; called by mutect2, pindel, varscan2
- CIC | c.3553G>A p.A1185T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs587778202; ClinVar: not provided; called by muse, mutect2, varscan2
- CLK3 | c.605G>A p.R202H (on ENST00000395066 / NM_001130028.1; = p.R54H on NM_003992.4) | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs780907715, COSV61414550; called by muse, mutect2, varscan2
- CNNM4 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs770083154; called by muse, mutect2, varscan2
- CNOT1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs369419200; called by muse, mutect2, varscan2
- CNTFR | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs753791400, COSV63634323; called by muse, mutect2, varscan2
- COQ8A | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 108/569 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs200000374, COSV64657811; called by muse, varscan2
- CPA3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs553767929; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs769538822; called by mutect2, varscan2
- CSMD3 | c.6010C>T p.P2004S (on ENST00000297405 / NM_001363185.1; = p.P1900S on NM_052900.3) | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs763889329, COSV52093492; called by muse, mutect2, varscan2
- CT47B1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV64891384; called by muse, mutect2, varscan2
- CTDP1 | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 144/819 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201937277; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 39/249 reads (16%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CYLD | c.2305A>T p.I769F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1489875475, CD051729, COSV61093604, COSV61095598; called by muse, mutect2, varscan2
- CYP1A1 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV101122381; called by muse, mutect2, varscan2
- CYP3A43 | c.747A>T p.L249F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767952577, COSV55938439; called by muse, mutect2, varscan2
- DAZAP1 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.617); catalogued as rs1189634555; called by muse, mutect2
- DCT | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs772228009, COSV65468706; called by muse, mutect2, varscan2
- DCTN1 | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs778421133; called by muse, mutect2, varscan2
- DDX1 | c.956+2T>C p.X319_splice | Splice Site (SNP) | VAF 20/116 reads (17%) | catalogued as rs1450424612; called by muse, mutect2
- DDX3X | c.593G>A p.R198H (on ENST00000399959; = p.R199H on NM_001356.5) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs755750366, COSV67864226; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DHX9 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.043); catalogued as COSV62358954; called by muse, mutect2, varscan2
- DIDO1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1268237438; called by muse, mutect2, varscan2
- DLGAP2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs772857180, COSV70103012; called by muse, mutect2, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 66/356 reads (19%) | catalogued as rs760008381; called by mutect2, varscan2
- DNAJC24 | c.29dup p.D11Gfs*32 | Frame Shift Ins (INS) | VAF 26/149 reads (17%) | catalogued as rs1189929131; called by mutect2, pindel, varscan2
- DOCK3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56538547, COSV56539664; called by muse, mutect2, varscan2
- DOCK6 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs369679393; called by muse, mutect2, varscan2
- DPEP2 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs779298810; called by muse, mutect2, varscan2
- DSC3 | c.1530dup p.L511Ifs*3 | Frame Shift Ins (INS) | VAF 34/248 reads (14%) | catalogued as rs1317680492; called by pindel, varscan2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs758962538; called by mutect2, pindel, varscan2
- DUXB | c.344del p.N115Tfs*3 | Frame Shift Del (DEL) | VAF 46/324 reads (14%) | catalogued as rs956480172; called by mutect2, varscan2
- DYRK1A | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs1469221964, COSV58296611; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDEM1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs745778225; called by muse, mutect2, varscan2
- EDNRB | c.536del p.P179Rfs*35 (on ENST00000377211 / NM_001201397.1; = p.P89Rfs*35 on NM_000115.5) | Frame Shift Del (DEL) | VAF 27/168 reads (16%) | catalogued as COSV57524395; called by mutect2, pindel
- EFEMP1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 139/650 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV62614980; called by muse, mutect2, varscan2
- EGR2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 81/461 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV54346848, COSV54346961; called by muse, mutect2, varscan2
- ELMO1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs146510671; called by muse, mutect2
- EML2 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1437040403, COSV99840022; called by muse, mutect2
- ENG | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 89/436 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs548690138; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs761717176; called by mutect2, varscan2
- EPG5 | c.5704dup p.Y1902Lfs*2 | Frame Shift Ins (INS) | VAF 32/128 reads (25%) | catalogued as rs760768451; called by mutect2, varscan2
- EPX | c.786dup p.C263Lfs*10 | Frame Shift Ins (INS) | VAF 62/349 reads (18%) | catalogued as rs1409507270; called by mutect2, pindel, varscan2
- ESPNL | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as rs1339572829, COSV58036666; called by muse, mutect2, varscan2
- ESRRA | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs61739389; called by muse, mutect2, varscan2
- EXOC3 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs373192597; called by muse, mutect2, varscan2
- EXTL1 | c.1163dup p.G389Rfs*28 | Frame Shift Ins (INS) | VAF 26/212 reads (12%) | catalogued as rs769641599; called by mutect2, pindel
- F2RL3 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs567639376; called by muse, mutect2, varscan2
- FAAP100 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV59886487; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 34/234 reads (15%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM228B | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as rs527821741; called by muse, mutect2
- FAM47C | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 140/672 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as COSV63725679; called by muse, varscan2
- FAM50B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs748727501, COSV66654711; called by muse, mutect2, varscan2
- FAM83E | c.1305del p.A436Pfs*105 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | catalogued as COSV99572212; called by mutect2, pindel, varscan2
- FANCM | c.4270C>T p.R1424* | Nonsense Mutation (SNP) | VAF 17/150 reads (11%) | catalogued as rs751954386; called by muse, mutect2, varscan2
- FASTKD2 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs747511083; called by muse, mutect2, varscan2
- FAT3 | c.8852G>C p.R2951T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs375952962; called by muse, varscan2
- FAT4 | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV101272929; called by muse, mutect2, varscan2
- FBLL1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1276949754; called by muse, mutect2, varscan2
- FBXO46 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs770220571; called by muse, mutect2, varscan2
- FCRL5 | c.2896G>A p.G966R | Missense Mutation (SNP) | VAF 66/378 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs377397519; called by muse, mutect2, varscan2
- FER1L5 | c.5056C>T p.R1686C (on ENST00000623019; = p.R1659C on NM_001293083.2) | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1407069652, COSV67605669; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLYWCH1 | c.493C>T p.R165W (on ENST00000253928 / NM_001308068.2; = p.R164W on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369819775; called by muse, mutect2, varscan2
- FMO4 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.828); catalogued as rs770794489; called by muse, mutect2, varscan2
- FNDC3B | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.082); catalogued as rs190147254; called by muse, mutect2, varscan2
- FOSL2 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs370838431; called by muse, mutect2, varscan2
- FPR3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs770018978, COSV59328030; called by muse, mutect2, varscan2
- GABBR2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs58390852; called by muse, mutect2
- GAL3ST3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762451590, COSV61749629; called by mutect2, varscan2
- GBP6 | c.1760del p.N587Mfs*18 | Frame Shift Del (DEL) | VAF 48/304 reads (16%) | catalogued as rs1557544730; called by mutect2, pindel, varscan2
- GEMIN4 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs369914416; called by muse, mutect2, varscan2
- GIMAP1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.904); catalogued as COSV56187144; called by muse, mutect2, varscan2
- GIMAP6 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs868377767, COSV100188306; called by muse, mutect2, varscan2
- GIMAP8 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs148465635; called by muse, mutect2, varscan2
- GJA3 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs770766676, COSV53834166; called by muse, mutect2, varscan2
- GJD4 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV58703219; called by muse, mutect2
- GLIS1 | c.501del p.Y168Ifs*116 | Frame Shift Del (DEL) | VAF 43/235 reads (18%) | catalogued as rs1404881982; called by mutect2, pindel, varscan2
- GLP2R | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs114273181, COSV104389432; called by muse, mutect2, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs1489322870; called by mutect2, pindel, varscan2
- GPATCH8 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs777367404, COSV59194801; called by muse, mutect2, varscan2
- GPBP1L1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 71/429 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs140154727; called by muse, mutect2, varscan2
- GPR22 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51744993; called by muse, mutect2, varscan2
- GREB1 | c.2771C>T p.T924M | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755805775, COSV52191366; called by muse, mutect2, varscan2
- GRIK3 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV100901770; called by muse, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs754199513; called by mutect2, varscan2
- GUCY2C | c.1120dup p.D374Gfs*3 | Frame Shift Ins (INS) | VAF 25/182 reads (14%) | catalogued as rs746745578; called by mutect2, pindel, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 16/186 reads (9%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel
- HBA2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 45/960 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs34695138, CM950607; called by muse, mutect2
- HELZ2 | c.7138G>A p.A2380T (on ENST00000467148 / NM_001037335.2; = p.A1811T on NM_033405.3) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1191781679; called by muse, mutect2
- HIP1R | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142435037; called by muse, mutect2, varscan2
- HK1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771221778; called by muse, mutect2, varscan2
- HMMR | c.1266-1G>A p.X422_splice | Splice Site (SNP) | VAF 40/148 reads (27%) | catalogued as COSV62375281; called by muse, mutect2, varscan2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 34/154 reads (22%) | catalogued as rs761024113; called by mutect2, varscan2
- HSPA12A | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782368186, COSV65023005; called by muse, mutect2, varscan2
- HYDIN | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs773574100; called by muse, mutect2, varscan2
- HYLS1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs370135175; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFT46 | c.587C>T p.A196V (on ENST00000264021 / NM_001168618.2; = p.A247V on NM_020153.3) | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs201190647, COSV50595218; called by muse, mutect2, varscan2
- IGSF10 | c.2946C>A p.F982L | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1249211948; called by muse, mutect2, varscan2
- IL26 | c.188del p.N63Ifs*5 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | catalogued as rs778805733; called by mutect2, pindel, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 59/329 reads (18%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- IL7R | c.1106G>T p.C369F | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs758381888, COSV57414726; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | catalogued as rs760925109; called by mutect2, varscan2
- IRS1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 82/390 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs1382730133; called by muse, mutect2, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel
- ITGA11 | c.1339del p.R447Gfs*30 | Frame Shift Del (DEL) | VAF 44/288 reads (15%) | catalogued as COSV100241911; called by mutect2, pindel, varscan2
- ITK | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 124/571 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138438785, CM137505; ClinVar: uncertain significance; called by muse, varscan2
- KATNIP | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181515149, COSV55192238; called by muse, mutect2, varscan2
- KCND3 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56175499; called by muse, mutect2, varscan2
- KCNH2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1325776019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ12 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs782612333, COSV100054817; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KDM2B | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1555288034, COSV65641902; called by muse, mutect2, varscan2
- KIAA1549L | c.1510C>A p.L504I (on ENST00000321505; = p.L801I on NM_012194.3) | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV55773116; called by mutect2, varscan2
- KIF16B | c.2246del p.K749Rfs*3 | Frame Shift Del (DEL) | VAF 53/259 reads (20%) | catalogued as rs35229389; called by mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/251 reads (22%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF7 | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747632760, COSV51544087; called by muse, mutect2, varscan2
- KIRREL3 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 64/656 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as rs374832017; called by muse, mutect2
- KLHL22 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.971); catalogued as rs1312402474; called by muse, mutect2, varscan2
- KLHL26 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as rs773255884; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as rs749194179; called by mutect2, pindel
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KRT32 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs374925222, COSV56785924; called by muse, mutect2, varscan2
- LDB3 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 89/430 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as rs368053281; called by muse, mutect2, varscan2
- LGI1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs757480776, COSV65059189; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as rs775423572; called by mutect2, varscan2
- LILRA6 | c.1406A>G p.Q469R | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752551475; called by muse, mutect2
- LILRB2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 74/482 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs201242685, COSV58748743; called by muse, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 32/153 reads (21%) | catalogued as rs765287063; called by mutect2, varscan2
- LMNTD2 | c.34+1G>T p.X12_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as rs1421447053; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 52/272 reads (19%) | catalogued as rs748712732; called by mutect2, varscan2
- LRCH3 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58396573; called by muse, mutect2, varscan2
- LRFN1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as rs1344712701, COSV50436246; called by muse, mutect2, varscan2
- LRFN4 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs867603133; called by muse, mutect2, varscan2
- LRGUK | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs962001273, COSV99603883; called by muse, mutect2, varscan2
- LRRC47 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749845846, COSV65562557; called by muse, mutect2, varscan2
- LTB4R | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51865321; called by muse, mutect2
- MAGEB6B | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs775868139; called by muse, mutect2, varscan2
- MAN2B1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 63/429 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs754036398, CM124075; called by muse, mutect2, varscan2
- MAP2 | c.4807C>A p.P1603T | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562159; called by muse, mutect2, varscan2
- MAP3K9 | c.3257C>T p.A1086V (on ENST00000554752 / NM_001284230.1; = p.A1100V on NM_033141.4) | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs776047235, COSV67121634; called by muse, mutect2, varscan2
- MAPKBP1 | c.4304G>T p.R1435L (on ENST00000456763 / NM_001128608.2; = p.R1429L on NM_014994.3) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs759363306; called by muse, mutect2, varscan2
- MARVELD3 | c.542_543del p.E181Gfs*67 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs762245773; called by pindel, varscan2
- MCL1 | c.55dup p.A19Gfs*91 | Frame Shift Ins (INS) | VAF 30/193 reads (16%) | catalogued as rs750805885; called by mutect2, varscan2
- MCMDC2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs774182901, COSV58033832, COSV58040182; called by muse, mutect2, varscan2
- MDP1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs377711229; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 31/237 reads (13%) | catalogued as rs765803753; called by mutect2, pindel, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 33/218 reads (15%) | catalogued as rs755830405; called by mutect2, varscan2
- MPRIP | c.2129G>T p.R710L | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs767185147; called by muse, mutect2, varscan2
- MPV17L | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs1445631252, COSV99806241; called by muse, mutect2
- MRTFB | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100371482; called by muse, mutect2, varscan2
- MSANTD4 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57286109; called by muse, mutect2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | catalogued as rs764857791; called by mutect2, pindel
- MYH11 | c.5359C>T p.R1787W | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs142198104, COSV100259776; called by muse, mutect2, varscan2
- MYO18A | c.1678C>A p.L560I | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs1457202533; called by muse, mutect2, varscan2
- NAA16 | c.1548del p.F516Lfs*3 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | catalogued as rs749241638; called by mutect2, pindel
- NAPRT | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs532818404; called by mutect2, varscan2
- NCF1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1375017077; called by mutect2, varscan2
- NEIL1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs576861338, COSV99145889; called by muse, mutect2, varscan2
- NEK7 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66314751, COSV66315611; called by muse, mutect2, varscan2
- NLGN4X | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs761689770; called by muse, mutect2, varscan2
- NLN | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779515643, COSV66767263; called by muse, mutect2, varscan2
- NMT2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.108); catalogued as rs756100960; called by muse, mutect2, varscan2
- NOL6 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs376740139; called by muse, mutect2, varscan2
- NOL6 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369599517; called by muse, mutect2, varscan2
- NPAS4 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1165080182; called by muse, mutect2, varscan2
- NR1I3 | c.1022C>T p.S341F (on ENST00000367982 / NM_001077480.3; = p.S337F on NM_005122.5) | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.041); catalogued as COSV100915489; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 20/146 reads (14%) | catalogued as rs774343392; called by mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | catalogued as rs776154715; called by mutect2, varscan2
- NUP210 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs761045444; called by muse, mutect2, varscan2
- NUP43 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 87/498 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1207377977; called by muse, mutect2, varscan2
- OBSL1 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs760985580; called by muse, mutect2, varscan2
- OGFR | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1030189708; called by muse, mutect2
- OPCML | c.536del p.G179Afs*3 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | catalogued as COSV59409983; called by mutect2, pindel, varscan2
- OR10K1 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56871350; called by muse, mutect2, varscan2
- OR1L1 | c.865del p.S289Lfs*10 (on ENST00000373686; = p.S239Lfs*10 on NM_001005236.3) | Frame Shift Del (DEL) | VAF 26/199 reads (13%) | catalogued as rs759559271; called by mutect2, pindel, varscan2
- OR2AG2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs569276635, COSV58455025; called by muse, mutect2, varscan2
- OR6V1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV69237744; called by muse, mutect2, varscan2
- OSBPL11 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.989); catalogued as rs773104875; called by muse, mutect2, varscan2
- OSCAR | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV52928296; called by muse, mutect2, varscan2
- OTOP1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1253655908, COSV99588190; called by muse, mutect2, varscan2
- OTOP2 | c.41del p.P14Rfs*24 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs1038793108; called by mutect2, pindel, varscan2
- P3H2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 110/575 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537288155, COSV60024619; called by muse, mutect2, varscan2
- P4HA2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs201062782, COSV51325010; called by muse, mutect2, varscan2
- PALD1 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746010656, COSV54976421; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 68/388 reads (18%) | catalogued as CM011452; called by mutect2, varscan2
- PCDH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752356781, COSV57265804, COSV57366433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA13 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 109/603 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as rs782229727, COSV56476082; called by muse, mutect2, varscan2
- PCDHA2 | c.2295del p.K766Rfs*29 | Frame Shift Del (DEL) | VAF 76/352 reads (22%) | catalogued as rs558931090, COSV65368078; called by mutect2, pindel, varscan2
- PCDHA3 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 42/927 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs139431952; called by muse, mutect2
- PCDHA4 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 72/390 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs370475370; called by muse, mutect2, varscan2
- PCDHB12 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 182/944 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as COSV53392735, COSV53399515; called by muse, varscan2
- PCDHB7 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 189/967 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV50818287; called by muse, mutect2
- PCDHGB1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV54048141; called by muse, mutect2, varscan2
- PDCD6IP | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.155); catalogued as COSV100219283; called by muse, mutect2
- PDXK | c.760-3C>T | Splice Region (SNP) | VAF 16/227 reads (7%) | catalogued as rs772247173, COSV99375966; called by muse, mutect2
- PDZRN3 | c.3071del p.K1024Rfs*2 | Frame Shift Del (DEL) | VAF 41/230 reads (18%) | catalogued as rs1559644155; called by mutect2, pindel, varscan2
- PFKFB4 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 35/254 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs781535165, COSV99219983; called by muse, mutect2, varscan2
- PIK3C2A | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as rs1293039936; called by muse, mutect2, varscan2
- PITPNM2 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs952177392; called by muse, mutect2, varscan2
- PKHD1L1 | c.12491dup p.N4164Kfs*3 | Frame Shift Ins (INS) | VAF 16/125 reads (13%) | catalogued as rs777196555; called by pindel, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 32/199 reads (16%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLEKHG6 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1301347530, COSV50598505, COSV50605696; called by muse, mutect2, varscan2
- PLXNB3 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as rs782511958, COSV62798084; called by muse, mutect2
- PLXNB3 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs371248419; called by muse, mutect2, varscan2
- POLD1 | c.537del p.R180Gfs*3 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | catalogued as COSV70957044; called by mutect2, pindel, varscan2
- POLE | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200825008, COSV100265990; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLQ | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1252138781; called by muse, mutect2, varscan2
- POLR2F | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1569172527, COSV61005955; called by muse, mutect2, varscan2
- POM121L2 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV66276709; called by muse, mutect2, varscan2
- PON2 | c.832del p.D278Tfs*4 | Frame Shift Del (DEL) | VAF 75/466 reads (16%) | catalogued as COSV56002394; called by mutect2, pindel, varscan2
- PPIC | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217806551, COSV60575464; called by muse, mutect2, varscan2
- PPP1R10 | c.2084del p.G695Vfs*222 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs760405117; called by mutect2, pindel
- PPP1R26 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100778041; called by muse, mutect2, varscan2
- PRKAR1A | c.-6-5C>T | Splice Region (SNP) | VAF 58/307 reads (19%) | catalogued as rs750536611, COSV62235921; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKAR1B | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs376485407; called by muse, mutect2, varscan2
- PRKCB | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100332094; called by muse, mutect2, varscan2
- PRPF40B | c.2096G>A p.G699D (on ENST00000380281; = p.G686D on NM_012272.3) | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1261520211; called by muse, mutect2, varscan2
- PRRX1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1270473736, CM143963, COSV53413010; called by muse, mutect2, varscan2
- PSMD12 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447169912; called by muse, mutect2, varscan2
- PTCHD3 | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 47/232 reads (20%) | catalogued as COSV101438815; called by muse, mutect2, varscan2
- PUF60 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1239200237; called by muse, mutect2, varscan2
- RAB11FIP3 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs748822573; called by muse, mutect2, varscan2
- RAB11FIP5 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs768652292; called by muse, mutect2, varscan2
- RAB3D | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs770656530; called by muse, mutect2, varscan2
- RABL3 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs138084643; called by muse, mutect2, varscan2
- RAD21 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs760261220, COSV52056170, COSV52059469; called by muse, mutect2, varscan2
- RBM19 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1276840568; called by muse, mutect2, varscan2
- RBM23 | c.109A>G p.N37D | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs747283693; called by muse, mutect2, varscan2
- RBMX | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV57810930; called by muse, mutect2, varscan2
- RCN2 | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100312914; called by muse, varscan2
- RELCH | c.2411G>A p.R804H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs764785928; called by muse, mutect2, varscan2
- RELN | c.7432G>A p.G2478R | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58998103; called by muse, mutect2, varscan2
- RIN1 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs750626463; called by muse, mutect2, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 30/197 reads (15%) | catalogued as COSV59688684; called by mutect2, pindel, varscan2
- RNF220 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); catalogued as rs767216789; called by muse, mutect2, varscan2
- RPTOR | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs770010373; called by muse, mutect2, varscan2
- RTL5 | c.1643del p.P548Lfs*52 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as COSV101030286; called by mutect2, pindel, varscan2
- RTN1 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1566701048, COSV50723706; called by muse, mutect2, varscan2
- S1PR3 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs768573223, COSV63980110; called by muse, mutect2, varscan2
- SAGE1 | c.209A>T p.D70V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV61015820; called by muse, mutect2, varscan2
- SALL1 | c.2150G>A p.C717Y | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51757159; called by muse, mutect2, varscan2
- SAMD12 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 51/373 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV100126604; called by muse, mutect2, varscan2
- SCAF1 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs938184013; called by mutect2, varscan2
- SCAPER | c.2954A>G p.K985R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV57738572; called by muse, mutect2, varscan2
- SCART1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.875); catalogued as rs1018427255; called by muse, mutect2, varscan2
- SCN11A | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs868074183, COSV56567556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRT2 | c.896del p.P299Rfs*46 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as rs771985405; called by mutect2, pindel, varscan2
- SDCCAG8 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as rs369591883; called by muse, mutect2, varscan2
- SDK2 | c.3761A>G p.E1254G | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs766107690; called by muse, mutect2, varscan2
- SEMA3F | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1177203082; called by muse, mutect2, varscan2
- SENP6 | c.432A>G p.I144M | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1276375508; called by muse, mutect2, varscan2
- SEPTIN4 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs370660253, COSV58728663; called by muse, mutect2
- SERAC1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs907800844; called by muse, varscan2
- SETDB1 | c.2625del p.C876Vfs*8 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | catalogued as COSV99644797; called by mutect2, pindel, varscan2
- SH3TC1 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1425571815; called by muse, mutect2, varscan2
- SIM1 | c.1803dup p.H602Tfs*16 | Frame Shift Ins (INS) | VAF 28/168 reads (17%) | catalogued as rs1442473894; called by mutect2, varscan2
- SIPA1L2 | c.4606G>A p.A1536T | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs567382979; called by muse, mutect2
- SIVA1 | c.313+5G>A | Splice Region (SNP) | VAF 57/249 reads (23%) | catalogued as rs1320255676; called by muse, mutect2, varscan2
- SLC12A5 | c.2408G>A p.R803H (on ENST00000454036 / NM_001134771.2; = p.R780H on NM_020708.5) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs779096129, COSV54793253; called by muse, mutect2, varscan2
- SLC16A11 | c.827del p.G276Dfs*43 (on ENST00000308009; = p.G252Dfs*43 on NM_153357.3) | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as COSV99080391; called by mutect2, pindel, varscan2
- SLC16A14 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.257); catalogued as COSV54617278; called by muse, mutect2, varscan2
- SLC2A10 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1568985841, COSV63714075; called by muse, mutect2, varscan2
- SLC2A12 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51602590; called by muse, mutect2, varscan2
- SLC4A2 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs751114100; called by muse, mutect2, varscan2
- SLC7A5 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as rs754582725; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 51/289 reads (18%) | catalogued as rs747405143; called by mutect2, varscan2
- SPIN4 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs1556016571, COSV58738788; called by muse, mutect2, varscan2
- SPTAN1 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.717); catalogued as rs759822213, COSV63989617; ClinVar: benign; called by muse, mutect2, varscan2
- SPTBN4 | c.6874C>T p.R2292W | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as rs762255596, COSV58950639; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs748467821; called by mutect2, varscan2
- SRSF4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441731561, COSV65695639; called by muse, varscan2
- STK31 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1253097391, COSV63459496; called by muse, mutect2, varscan2
- STXBP1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 100/419 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs773211322; called by muse, mutect2, varscan2
- SUSD2 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756917943; called by muse, varscan2
- SYNPO | c.1048C>T p.P350S (on ENST00000394243 / NM_001166208.2; = p.P106S on NM_007286.6) | Missense Mutation (SNP) | VAF 102/634 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs774852438; called by muse, mutect2, varscan2
- SYNPO | c.2674G>A p.V892M (on ENST00000394243 / NM_001166208.2; = p.V648M on NM_007286.6) | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs758659255, COSV56942206; called by muse, mutect2, varscan2
- TAF2 | c.1278-3del | Splice Region (DEL) | VAF 24/156 reads (15%) | catalogued as rs751147458; called by mutect2, varscan2
- TASOR | c.4445dup p.N1483Efs*5 (on ENST00000355628 / NM_001365636.2; = p.N1107Efs*5 on NM_015224.3) | Frame Shift Ins (INS) | VAF 30/143 reads (21%) | catalogued as rs1418826116; called by mutect2, varscan2
- TBC1D20 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 89/559 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as rs780055180, COSV62612298; called by muse, mutect2, varscan2
- TBC1D22A | c.96dup p.F33Lfs*2 | Frame Shift Ins (INS) | VAF 34/236 reads (14%) | catalogued as rs771822190; called by mutect2, varscan2
- TBCD | c.1072del p.V358Wfs*4 | Frame Shift Del (DEL) | VAF 28/139 reads (20%) | catalogued as COSV62797976; called by mutect2, pindel, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 61/280 reads (22%) | catalogued as rs748952707, COSV56876494; called by mutect2, varscan2
- TCF4 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752176058; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs763321097; called by mutect2, varscan2
- TERT | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs943289163; called by muse, mutect2
- TET1 | c.65del p.K22Rfs*23 | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | catalogued as rs1196853334; called by mutect2, varscan2
- TEX33 | c.340C>G p.Q114E (on ENST00000381821 / NM_001163857.2; = p.Q29E on NM_178552.4) | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV67822632; called by muse, mutect2, varscan2
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | catalogued as rs771133493, COSV55406589; called by mutect2, pindel
- TGIF1 | c.662C>T p.P221L (on ENST00000330513 / NM_001374396.1; = p.P241L on NM_003244.4) | Missense Mutation (SNP) | VAF 77/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1218392695; called by muse, mutect2, varscan2
- TGM1 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 116/568 reads (20%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.832); catalogued as CM092039, COSV52865380; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM64 | c.943dup p.C315Lfs*30 | Frame Shift Ins (INS) | VAF 17/127 reads (13%) | catalogued as rs1563955623; called by mutect2, pindel
- TMPRSS4 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1193513442, COSV71110720; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs754233336; called by mutect2, pindel
- TOP1MT | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1310928083, COSV61316348; called by muse, mutect2, varscan2
- TRANK1 | c.4261del p.D1421Tfs*7 | Frame Shift Del (DEL) | VAF 38/202 reads (19%) | catalogued as rs866661054; called by mutect2, pindel, varscan2
- TRAP1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55918090; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | catalogued as rs763121810; called by mutect2, varscan2
- TRPM2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs377142675; called by muse, varscan2
- TRRAP | c.9188G>T p.R3063L (on ENST00000359863 / NM_001244580.1; = p.R3034L on NM_003496.3) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62844029; called by muse, mutect2, varscan2
- TSBP1 | c.670del p.S224Lfs*8 (on ENST00000617061; = p.S227Lfs*8 on NM_006781.5) | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | catalogued as COSV66660771; called by mutect2, varscan2
- TTC6 | c.772G>A p.G258S (on ENST00000267368; = p.G1624S on NM_001310135.3) | Missense Mutation (SNP) | VAF 72/388 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs988647067; called by muse, mutect2, varscan2
- TTN | c.94678C>A p.P31560T (on ENST00000591111; = p.P24136T on NM_003319.4) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV100600804; called by muse, mutect2, varscan2
- TUBGCP6 | c.5426G>A p.R1809H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs540957245, COSV99955171; called by muse, mutect2, varscan2
- U2AF2 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779075792, COSV58276793; called by mutect2, varscan2
- UBR1 | c.4547T>C p.F1516S | Missense Mutation (SNP) | VAF 92/447 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99316680; called by muse, mutect2, varscan2
- UNC45A | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs528888745; called by muse, mutect2, varscan2
- UNC79 | c.1613C>T p.A538V (on ENST00000393151 / NM_001346218.2; = p.A361V on NM_020818.5) | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767462239, COSV56374428; called by muse, mutect2, varscan2
- UNC80 | c.8834C>T p.T2945M | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1475238797, COSV55913284; called by muse, mutect2
- USH2A | c.10546A>G p.T3516A | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV56406483; called by muse, mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 49/218 reads (22%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP28 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs745453193, COSV50156931; called by muse, mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs761345427; called by mutect2, pindel
- USP42 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs997777205; called by muse, mutect2, varscan2
- USP46 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV71512732; called by muse, mutect2, varscan2
- USP7 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61214963; called by muse, mutect2
- UTP4 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 121/631 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760350216; called by muse, mutect2, varscan2
- VASP | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761788688, COSV55607551; called by muse, mutect2, varscan2
- VEGFB | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs565765277; called by muse, varscan2
- VEZF1 | c.113del p.P38Lfs*11 | Frame Shift Del (DEL) | VAF 43/227 reads (19%) | catalogued as COSV99365655; called by mutect2, pindel, varscan2
- VIM | c.1008C>T p.T336= | Splice Region (SNP) | VAF 89/465 reads (19%) | catalogued as rs111932484; called by muse, mutect2, varscan2
- VPS33A | c.1376del p.G459Afs*86 | Frame Shift Del (DEL) | VAF 17/130 reads (13%) | catalogued as rs1357715083, COSV57357082; called by mutect2, pindel, varscan2
- WDR45B | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 110/604 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs748362948; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR77 | c.25del p.L9* | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs769189971; called by mutect2, varscan2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | catalogued as rs752097396; called by mutect2, varscan2
- WNK3 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs374080880; called by muse, mutect2, varscan2
- WNT11 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 72/439 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs781536011, COSV100490231; called by muse, mutect2, varscan2
- XIRP1 | c.3578G>A p.R1193Q | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs150518280, COSV100453526; called by muse, mutect2, varscan2
- XPR1 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751223491; called by muse, mutect2, varscan2
- YAF2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs769223015, COSV100586509, COSV100586515; called by muse, varscan2
- ZC3H12C | c.59dup p.N20Kfs*10 | Frame Shift Ins (INS) | VAF 42/169 reads (25%) | catalogued as rs1213644414; called by mutect2, pindel
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 42/216 reads (19%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC8 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs750863956; called by muse, mutect2, varscan2
- ZFP36L2 | c.683del p.G228Afs*233 | Frame Shift Del (DEL) | VAF 59/314 reads (19%) | catalogued as COSV99144234; called by mutect2, pindel, varscan2
- ZFP36L2 | c.431dup p.G145Rfs*329 | Frame Shift Ins (INS) | VAF 66/472 reads (14%) | catalogued as rs1558428769; called by mutect2, pindel, varscan2
- ZNF236 | c.2423C>T p.T808M | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs754057667, COSV53496392; called by muse, mutect2, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs774038489; called by mutect2, pindel, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF317 | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1424258784; called by muse, mutect2, varscan2
- ZNF415 | c.277dup p.I93Nfs*5 | Frame Shift Ins (INS) | VAF 24/148 reads (16%) | catalogued as rs779446741; called by mutect2, varscan2
- ZNF45 | c.1787_1788del p.R596Ifs*19 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | catalogued as rs768662657; called by pindel, varscan2
- ZNF506 | c.183del p.K61Nfs*3 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as rs747582998; called by mutect2, pindel, varscan2
- ZNF541 | c.692dup p.E232Gfs*50 | Frame Shift Ins (INS) | VAF 20/118 reads (17%) | catalogued as rs780386192; called by mutect2, varscan2
- ZNF569 | c.1183T>C p.S395P | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs139833026; called by muse, mutect2, varscan2
- ZNF574 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV55902727, COSV55904635; called by muse, mutect2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF699 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as rs757840909, COSV58025150; called by muse, mutect2, varscan2
- ZNF837 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as rs972389511; called by muse, mutect2, varscan2
- ZNF850 | c.346A>G p.S116G | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as COSV74024531; called by muse, mutect2, varscan2
- ZNF852 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs778355777; called by muse, mutect2, varscan2
- ZSCAN10 | c.1514C>T p.T505M (on ENST00000252463; = p.T560M on NM_032805.3) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs984874719, COSV99374191; called by muse, mutect2, varscan2
- ZXDA | c.622del p.Q208Kfs*22 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as COSV100699390; called by mutect2, varscan2
- ABCA12 | c.6170A>G p.K2057R (on ENST00000272895 / NM_173076.3; = p.K1739R on NM_015657.3) | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCA13 | c.2798T>C p.L933P | Missense Mutation (SNP) | VAF 99/563 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABI3 | c.395del p.P132Lfs*183 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | called by mutect2, pindel, varscan2
- AC008676.3 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ACACA | c.3246+2T>C p.X1082_splice | Splice Site (SNP) | VAF 53/288 reads (18%) | called by muse, mutect2, varscan2
- ACOXL | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ACVR1C | c.496del p.T166Lfs*2 | Frame Shift Del (DEL) | VAF 38/274 reads (14%) | called by mutect2, pindel, varscan2
- ADAM33 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADAMTS10 | c.2874del p.S959Afs*114 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel
- ADAMTS20 | c.5165del p.N1722Tfs*17 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- ADCY6 | c.2183T>G p.L728R | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ADCY9 | c.3707A>G p.Q1236R | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL1 | c.3947del p.G1316Afs*217 (on ENST00000340736 / NM_001008701.3; = p.G1311Afs*217 on NM_014921.5) | Frame Shift Del (DEL) | VAF 22/138 reads (16%) | called by mutect2, pindel, varscan2
- ADRM1 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AEBP1 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AHCTF1 | c.4826C>T p.A1609V (on ENST00000366508; = p.A1583V on NM_015446.5) | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AHDC1 | c.3847A>G p.K1283E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2
- AHNAK | c.14157del p.K4720Rfs*9 | Frame Shift Del (DEL) | VAF 53/343 reads (15%) | called by mutect2, pindel, varscan2
- AIDA | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AKAP6 | c.6113G>A p.C2038Y | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- AKNA | c.1137del p.K380Sfs*30 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- ALDH1L2 | c.2619A>C p.K873N | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ALDH7A1 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 74/478 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ALKBH3 | c.749C>A p.A250E | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ALKBH4 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2
- AMBRA1 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); called by muse, varscan2
- ANGPTL3 | c.510del p.K170Nfs*20 | Frame Shift Del (DEL) | VAF 29/167 reads (17%) | called by mutect2, pindel, varscan2
- ANKH | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 110/643 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD11 | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 81/563 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ANKRD17 | c.7306A>G p.R2436G | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANKRD26 | c.2266del p.M756Wfs*18 | Frame Shift Del (DEL) | VAF 34/232 reads (15%) | called by mutect2, pindel, varscan2
- APOB | c.6222del p.F2074Lfs*16 | Frame Shift Del (DEL) | VAF 14/127 reads (11%) | called by mutect2, pindel, varscan2
- APOO | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AQP5 | c.433T>G p.C145G | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ARAP3 | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP17 | c.2644T>C p.*882Rext*108 (on ENST00000289968 / NM_001006634.3; = p.*804Rext*108 on NM_018054.6) | Nonstop Mutation (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2
- ARHGAP29 | c.3334C>T p.Q1112* | Nonsense Mutation (SNP) | VAF 77/493 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.2785del p.S929Lfs*32 | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, pindel
- ARHGAP33 | c.2150del p.P717Lfs*79 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- ARHGEF10L | c.2923C>A p.R975S | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ARHGEF2 | c.341-1G>A p.X114_splice (on ENST00000361247 / NM_001162383.2; = p.X87_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- ARID4B | c.3457A>G p.S1153G | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARMC1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARNT2 | c.1024A>G p.N342D | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARPC1B | c.990-1G>A p.X330_splice | Splice Site (SNP) | VAF 73/350 reads (21%) | called by muse, mutect2, varscan2
- ASMTL | c.1357T>A p.S453T | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP11C | c.1719dup p.P574Sfs*7 | Frame Shift Ins (INS) | VAF 17/152 reads (11%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.3440G>A p.G1147D | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ATP6AP1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATRX | c.1586T>A p.F529Y | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ATXN2 | c.3101A>G p.Y1034C (on ENST00000550104; = p.Y874C on NM_002973.4) | Missense Mutation (SNP) | VAF 32/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 44/276 reads (16%) | called by mutect2, varscan2
- BACE2 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by mutect2, varscan2
- BLNK | c.903-3C>A | Splice Region (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- BRSK2 | c.160_162del p.K54del | In Frame Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- BSG | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- BTK | c.-30-1G>A | Splice Site (SNP) | VAF 58/325 reads (18%) | called by muse, mutect2, varscan2
- C12orf40 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- C15orf39 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- C15orf39 | c.2736_2738del p.L913del | In Frame Del (DEL) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- C20orf194 | c.916A>G p.N306D | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- C20orf194 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- C3 | c.3869A>G p.Q1290R | Missense Mutation (SNP) | VAF 144/748 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- CABS1 | c.548del p.K183Rfs*6 | Frame Shift Del (DEL) | VAF 66/314 reads (21%) | called by mutect2, pindel, varscan2
- CACNA1S | c.5049-1G>A p.X1683_splice | Splice Site (SNP) | VAF 98/556 reads (18%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2133dup p.T712Yfs*3 (on ENST00000356253 / NM_001366867.1; = p.T700Yfs*3 on NM_000722.4) | Frame Shift Ins (INS) | VAF 35/205 reads (17%) | called by mutect2, pindel, varscan2
- CACNG3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CACNG4 | c.911A>C p.H304P | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel
- CAGE1 | c.1307G>A p.S436N (on ENST00000512086; = p.S300N on NM_205864.3) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CAMK1G | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CAMK2D | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN12 | c.1217del p.G406Afs*33 | Frame Shift Del (DEL) | VAF 25/169 reads (15%) | called by mutect2, pindel, varscan2
- CARD9 | c.1456del p.E486Sfs*97 | Frame Shift Del (DEL) | VAF 48/224 reads (21%) | called by mutect2, pindel, varscan2
- CATSPERG | c.3185G>A p.S1062N | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CCDC102B | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCDC113 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC158 | c.610del p.I204Yfs*23 | Frame Shift Del (DEL) | VAF 60/398 reads (15%) | called by mutect2, varscan2
- CCDC88A | c.3652del p.M1218Cfs*4 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- CCN4 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CCNJ | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCNL2 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CCSER1 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD300E | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- CD8A | c.509del p.G170Afs*122 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- CDAN1 | c.253A>T p.R85W | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CDK5RAP2 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPJ | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 50/318 reads (16%) | called by mutect2, varscan2
- CEP350 | c.3369del p.K1123Nfs*10 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | called by mutect2, varscan2
- CFAP65 | c.4234del p.D1412Tfs*69 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- CHAMP1 | c.1151del p.P384Lfs*201 | Frame Shift Del (DEL) | VAF 39/195 reads (20%) | called by mutect2, pindel, varscan2
- CHN2 | c.177-2A>C p.X59_splice | Splice Site (SNP) | VAF 38/188 reads (20%) | called by muse, mutect2, varscan2
- CHRD | c.2566del p.A856Pfs*40 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- CILP2 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- CKAP5 | c.3528del p.G1177Dfs*2 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- CLCN7 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- CLSPN | c.3071T>C p.L1024P | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMAS | c.158del p.G53Efs*8 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | called by mutect2, varscan2
- CNTN5 | c.3282_3284del p.M1094del | In Frame Del (DEL) | VAF 51/287 reads (18%) | called by pindel, varscan2
- COL6A1 | c.2683C>T p.Q895* | Nonsense Mutation (SNP) | VAF 38/525 reads (7%) | called by muse, mutect2
- COMT | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CPB2 | c.213del p.F71Lfs*2 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | called by pindel, varscan2
- CPT1A | c.1545del p.T516Pfs*15 | Frame Shift Del (DEL) | VAF 33/181 reads (18%) | called by mutect2, pindel, varscan2
- CRACDL | c.2340del p.D781Tfs*73 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- CTNND1 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); called by muse, mutect2
- CTPS2 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYB5R4 | c.66del p.R23Vfs*6 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | called by mutect2, pindel
- CYFIP1 | c.3264C>A p.C1088* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- CYP27C1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP4A11 | c.384G>C p.G128= | Splice Region (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- CYTH3 | c.95del p.K32Rfs*10 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2
- DDX60L | c.2329T>C p.Y777H | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DMD | c.5284C>A p.H1762N | Missense Mutation (SNP) | VAF 92/471 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DMRTA1 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DMRTA2 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- DMTN | c.36del p.S14Afs*2 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by mutect2, pindel, varscan2
- DND1 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 115/712 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DOCK2 | c.4647C>A p.A1549= | Splice Region (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- DOCK8 | c.4349C>T p.A1450V | Missense Mutation (SNP) | VAF 134/725 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSE | c.1595del p.N532Mfs*20 | Frame Shift Del (DEL) | VAF 40/190 reads (21%) | called by pindel, varscan2
- DYM | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, varscan2
- DYNC1H1 | c.10118C>T p.S3373F | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DYTN | c.1451A>G p.Q484R | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DYTN | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- EBF3 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- EED | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, varscan2
- EFCAB10 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EFHC1 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EFHC2 | c.1518G>T p.E506D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- EFHD1 | c.370del p.A124Pfs*8 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | called by mutect2, varscan2
- ELL2 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ENO4 | c.254_256dup p.T85_L86insP (on ENST00000622726; = p.T84_L85insP on NM_001242699.2) | In Frame Ins (INS) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- ENPP4 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EP400 | c.3319del p.H1107Ifs*5 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel
- EPHA1 | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHB4 | c.1039del p.L347Wfs*31 | Frame Shift Del (DEL) | VAF 49/238 reads (21%) | called by mutect2, pindel, varscan2
- ERBIN | c.2356del p.T786Hfs*11 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- ESF1 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ESF1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 70/292 reads (24%) | called by muse, mutect2, varscan2
- F12 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 89/412 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM47C | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 93/570 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, varscan2
- FAM47C | c.2989A>G p.I997V | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FAN1 | c.1906A>G p.R636G | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- FANCE | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 39/627 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- FARP2 | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2, varscan2
- FAT1 | c.7780C>T p.P2594S | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.6958_6959del p.Q2320Efs*36 | Frame Shift Del (DEL) | VAF 23/179 reads (13%) | called by pindel, varscan2
- FBXO15 | c.483dup p.Q162Tfs*11 | Frame Shift Ins (INS) | VAF 54/257 reads (21%) | called by mutect2, pindel, varscan2
- FCGBP | c.9263del p.G3088Afs*109 | Frame Shift Del (DEL) | VAF 101/495 reads (20%) | called by mutect2, pindel, varscan2
- FCGBP | c.4088G>T p.G1363V | Missense Mutation (SNP) | VAF 24/385 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNC | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- FMN2 | c.632A>T p.Q211L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- FMN2 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.077); called by muse, varscan2
- FNDC1 | c.4509del p.T1504Hfs*23 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- FOSL1 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.373); called by muse, mutect2
- FSIP2 | c.855_859del p.E286* | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | called by pindel, varscan2
- FSIP2 | c.3664del p.T1222Hfs*9 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- FZD2 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GAB3 | c.1076_1078del p.E359del | In Frame Del (DEL) | VAF 30/207 reads (14%) | called by mutect2, pindel, varscan2
- GAB3 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, varscan2
- GABRB2 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALR1 | c.57del p.A20Pfs*23 | Frame Shift Del (DEL) | VAF 30/141 reads (21%) | called by mutect2, pindel
- GAREM2 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF11 | c.638del p.G213Afs*12 | Frame Shift Del (DEL) | VAF 45/212 reads (21%) | called by mutect2, pindel, varscan2
- GLDN | c.1509G>T p.Q503H | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.081); called by muse, varscan2
- GLP2R | c.715T>G p.Y239D | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GP2 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPC4 | c.145del p.L49Sfs*9 | Frame Shift Del (DEL) | VAF 20/127 reads (16%) | called by mutect2, pindel, varscan2
- GPR63 | c.447dup p.G150Wfs*6 | Frame Shift Ins (INS) | VAF 33/244 reads (14%) | called by pindel, varscan2
- GPR75 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- GRIK3 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, varscan2
- GRM6 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GUCY2D | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- HACD3 | c.1073del p.K358Rfs*17 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- HARS1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by mutect2, varscan2
- HDAC2 | c.1375del p.T459Qfs*47 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- HECW1 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- HELQ | c.592T>G p.S198A | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- HEPH | c.277C>T p.P93S (on ENST00000343002; = p.P147S on NM_138737.5) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HERC2 | c.6482G>A p.G2161E | Missense Mutation (SNP) | VAF 100/580 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- HERC2 | c.3446C>T p.A1149V | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HES7 | c.197T>C p.L66S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- HIBCH | c.817del p.S273Qfs*21 | Frame Shift Del (DEL) | VAF 50/266 reads (19%) | called by mutect2, pindel, varscan2
- HIKESHI | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HLA-DOA | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2
- HNF4A | c.1137del p.S380Afs*14 | Frame Shift Del (DEL) | VAF 74/405 reads (18%) | called by mutect2, pindel, varscan2
- HS2ST1 | c.413T>C p.F138S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HSPD1 | c.419T>G p.I140S | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- IGHG3 | c.480A>G p.P160= | Splice Region (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- IGHM | c.686del p.P229Hfs*14 | Frame Shift Del (DEL) | VAF 107/581 reads (18%) | called by mutect2, pindel, varscan2
- IK | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- IL13RA1 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- IL22RA2 | c.753_755del p.R251del | In Frame Del (DEL) | VAF 38/148 reads (26%) | called by pindel, varscan2
- ILVBL | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IMMT | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INAVA | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- INPP5K | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- INTS14 | c.552G>T p.Q184H (on ENST00000313182 / NM_001366360.2; = p.Q105H on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- IQGAP3 | c.3938A>G p.E1313G | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.073); called by muse, varscan2
- IRF2BP1 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- IRX2 | c.745del p.L249Cfs*35 | Frame Shift Del (DEL) | VAF 70/318 reads (22%) | called by mutect2, pindel, varscan2
- IRX2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, varscan2
- ITGA5 | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAE | c.3456del p.F1152Lfs*8 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- ITGB1 | c.1624del p.D542Ifs*25 | Frame Shift Del (DEL) | VAF 23/155 reads (15%) | called by mutect2, pindel, varscan2
- JAKMIP3 | c.37del p.D13Tfs*72 | Frame Shift Del (DEL) | VAF 39/192 reads (20%) | called by mutect2, pindel, varscan2
- JMJD7-PLA2G4B | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
- KBTBD11 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNG1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- KCNH5 | c.677del p.F226Sfs*20 | Frame Shift Del (DEL) | VAF 31/189 reads (16%) | called by mutect2, pindel, varscan2
- KCNIP4 | c.199A>G p.R67G | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- KCNJ8 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD12 | c.53del p.G18Afs*21 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel
- KDM3A | c.2932G>T p.V978L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, varscan2
- KIAA0408 | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- KIAA0753 | c.1679del p.P560Qfs*16 | Frame Shift Del (DEL) | VAF 46/234 reads (20%) | called by mutect2, pindel, varscan2
- KIF15 | c.4093A>G p.R1365G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2
- KIF20B | c.5323C>T p.R1775* (on ENST00000371728 / NM_001284259.2; = p.R1735* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- KIF26B | c.3177G>C p.K1059N | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIF4B | c.2004del p.D669Tfs*4 | Frame Shift Del (DEL) | VAF 100/471 reads (21%) | called by mutect2, pindel, varscan2
- KLF13 | c.664_665dup p.G223Rfs*21 | Frame Shift Ins (INS) | VAF 46/251 reads (18%) | called by mutect2, varscan2
- KLHL34 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KLK12 | c.-19-3del | Splice Region (DEL) | VAF 23/187 reads (12%) | called by mutect2, pindel, varscan2
- KRT6A | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 36/652 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KSR1 | c.634A>G p.S212G (on ENST00000644974 / NM_001367810.1; = p.S75G on NM_014238.2) | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KTN1 | c.3302del p.K1101Rfs*18 (on ENST00000395314 / NM_001271014.2; = p.K1072Rfs*18 on NM_004986.4) | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | called by pindel, varscan2
- L3MBTL1 | c.731G>T p.R244M (on ENST00000418998 / NM_001377303.1; = p.R154M on NM_015478.7) | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LAMA2 | c.6983G>A p.C2328Y | Missense Mutation (SNP) | VAF 81/437 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA4 | c.2262del p.M755Wfs*5 (on ENST00000230538 / NM_001105206.3; = p.M748Wfs*5 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/356 reads (13%) | called by mutect2, pindel, varscan2
- LANCL3 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGMN | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LHCGR | c.1549A>G p.M517V | Missense Mutation (SNP) | VAF 15/403 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- LHX8 | c.878dup p.V294Sfs*35 | Frame Shift Ins (INS) | VAF 57/341 reads (17%) | called by mutect2, pindel, varscan2
- LIPM | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
- LPO | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- LRCH4 | c.1279del p.A427Pfs*8 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, varscan2
- LRP4 | c.1732dup p.R578Pfs*3 | Frame Shift Ins (INS) | VAF 75/348 reads (22%) | called by mutect2, pindel, varscan2
- LRRC7 | c.2575dup p.L859Pfs*30 (on ENST00000651989 / NM_001370785.2; = p.L826Pfs*30 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 31/185 reads (17%) | called by mutect2, pindel, varscan2
- LRRD1 | c.724del p.Y242Ifs*12 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- M1AP | c.237del p.F79Lfs*4 | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | called by mutect2, pindel, varscan2
- MAGEA1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MANEA | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MAP10 | c.1841del p.N614Tfs*28 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- MARK2 | c.1888del p.A630Pfs*27 (on ENST00000402010 / NM_001039469.2; = p.A575Pfs*18 on NM_004954.5) | Frame Shift Del (DEL) | VAF 55/287 reads (19%) | called by mutect2, pindel, varscan2
- MAS1L | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MDN1 | c.5965_5966del p.K1989Gfs*28 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- MEGF8 | c.3392del p.P1131Rfs*9 (on ENST00000251268 / NM_001271938.2; = p.P1064Rfs*9 on NM_001410.3) | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | called by mutect2, pindel, varscan2
- METTL3 | c.1116+2T>C p.X372_splice | Splice Site (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- MFGE8 | c.534dup p.H179Tfs*7 | Frame Shift Ins (INS) | VAF 62/409 reads (15%) | called by mutect2, pindel, varscan2
- MKRN3 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- MMP28 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- MOCS3 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- MPDZ | c.4684G>A p.A1562T | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MRC2 | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A2 | c.504dup p.E169* | Frame Shift Ins (INS) | VAF 84/531 reads (16%) | called by mutect2, pindel, varscan2
- MS4A5 | c.357A>G p.I119M | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2
- MTCL1 | c.5540A>G p.E1847G (on ENST00000306329 / NM_001378206.1; = p.E1528G on NM_015210.4) | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MTO1 | c.1406A>G p.E469G (on ENST00000370300 / NM_133645.3; = p.E444G on NM_012123.4) | Missense Mutation (SNP) | VAF 115/545 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MTUS2 | c.2687C>A p.S896Y | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- MUC16 | c.15998G>A p.S5333N | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MUC16 | c.6017A>G p.N2006S | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MUC2 | c.2674T>C p.Y892H | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.54); called by muse, mutect2, varscan2
- MXRA5 | c.4105T>C p.S1369P | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MXRA5 | c.1310T>C p.I437T | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MYH15 | c.4129A>G p.N1377D | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYH9 | c.4771-2A>G p.X1591_splice | Splice Site (SNP) | VAF 75/418 reads (18%) | called by muse, mutect2, varscan2
- MYO15A | c.10337G>A p.S3446N | Missense Mutation (SNP) | VAF 21/416 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.011); called by muse, mutect2
- MYRF | c.1663T>A p.F555I (on ENST00000278836 / NM_001127392.3; = p.F546I on NM_013279.4) | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- N4BP2 | c.3362C>T p.A1121V | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- NAA60 | c.*207-3C>T | Splice Region (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- NAA80 | c.828del p.R277Afs*48 (on ENST00000417393 / NM_001200018.2; = p.R299Afs*48 on NM_012191.4) | Frame Shift Del (DEL) | VAF 37/190 reads (19%) | called by mutect2, pindel, varscan2
- NCOA1 | c.2891del p.X964_splice | Splice Site (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- NDRG1 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- NEDD9 | c.341dup p.N114Kfs*39 | Frame Shift Ins (INS) | VAF 59/318 reads (19%) | called by mutect2, pindel, varscan2
- NEFM | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NELFB | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 66/255 reads (26%) | called by muse, mutect2, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 37/155 reads (24%) | called by mutect2, pindel, varscan2
- NES | c.1591A>G p.R531G | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NFAT5 | c.4313G>A p.G1438D | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- NFKB1 | c.1635T>C p.S545= (on ENST00000394820 / NM_001382627.1; = p.S546= on NM_003998.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
- NID2 | c.3258del p.T1087Pfs*15 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel
- NISCH | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/208 reads (17%) | called by mutect2, varscan2
- NKG7 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NKX1-1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH1 | c.7037T>C p.M2346T | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOX5 | c.1407del p.H470Tfs*10 | Frame Shift Del (DEL) | VAF 35/208 reads (17%) | called by mutect2, varscan2
- NPAS3 | c.647del p.P216Lfs*38 (on ENST00000356141 / NM_001164749.2; = p.P184Lfs*38 on NM_022123.3) | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | called by mutect2, pindel, varscan2
- NPAS3 | c.2058del p.S687Afs*123 (on ENST00000356141 / NM_001164749.2; = p.S655Afs*123 on NM_022123.3) | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | called by mutect2, varscan2
- NPLOC4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NPTX2 | c.1082del p.G361Vfs*138 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- NR4A2 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 52/693 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRIP1 | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSUN6 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- NSUN6 | c.327del p.K109Nfs*17 | Frame Shift Del (DEL) | VAF 30/203 reads (15%) | called by mutect2, pindel, varscan2
- NUB1 | c.357del p.D120Ifs*17 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- NUDT6 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- NUP214 | c.6198del p.F2066Lfs*77 | Frame Shift Del (DEL) | VAF 27/169 reads (16%) | called by mutect2, pindel, varscan2
- NUTM2G | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- OBSCN | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OLFML2A | c.1214del p.P405Lfs*2 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | called by mutect2, varscan2
- OR1C1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR6P1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8K5 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OTOGL | c.2595T>A p.N865K (on ENST00000547103; = p.N856K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PAAF1 | c.87A>G p.P29= | Splice Region (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2
- PDE3A | c.511del p.E171Kfs*36 | Frame Shift Del (DEL) | VAF 31/150 reads (21%) | called by mutect2, varscan2
- PDE4B | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PDZD2 | c.192del p.E65Kfs*21 | Frame Shift Del (DEL) | VAF 97/556 reads (17%) | called by mutect2, pindel, varscan2
- PEAR1 | c.755del p.P252Lfs*125 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- PGBD1 | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
605 further variants in this file (174 protein-altering or splice-affecting, 255 silent, 176 other) are not listed here.
